Gene-level copy-number profile of tumor specimen TCGA-NP-A5H6-01A from TCGA case TCGA-NP-A5H6, project TCGA-KICH (Kidney Chromophobe). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, chromophobe type; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage II; Age at diagnosis: 49.2 years (17,987 days).
Specimen TCGA-NP-A5H6-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 93e1d55e-a128-4d7f-802c-cdccbc57ff76.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator TCGA-NP-A5H6-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,726 have no estimate.
https://portal.gdc.cancer.gov/files/8f2d58d4-3100-491f-ba43-d14d3e09348c

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 12; copy number 1: 21,168; copy number 2: 37,700; copy number 3: 17.

Homozygous deletions (total copy number 0; autosomes only): 12 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:25,242,249–25,338,213, 6 genes (within-gene range 0–1): RSRP1, AL031432.3, AL031432.2, RHD, SDHDP6, AL928711.1.
- chr2:130,680,050–130,718,831, 4 genes: CYP4F30P, AC140481.3, FAR2P3, KLF2P3.
- chr17:46,372,855–46,509,339, 2 genes: NSFP1, RDM1P2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 18,312. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
